Somatic mutation profile of tumor specimen TCGA-BJ-A0YZ-01A (aliquot TCGA-BJ-A0YZ-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0YZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 66.0 years (24,102 days).
Specimen TCGA-BJ-A0YZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39891625-a31c-42fa-9695-87e92c4bb3a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0YZ-10A (Blood Derived Normal), aliquot TCGA-BJ-A0YZ-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/529792a2-9807-49f8-a03e-9ed360aa833f

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMH3 | c.1407-2A>G p.X469_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as COSV64236031; called by muse, mutect2, varscan2
- AXIN1 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.653); catalogued as COSV51989169; called by muse, mutect2, varscan2
- CCDC38 | c.266T>G p.F89C | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.527); catalogued as COSV60183726; called by muse, mutect2
- CDH8 | c.2086C>G p.P696A | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.166); catalogued as COSV54878435; called by muse, mutect2, varscan2
- DDX3Y | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60177031; called by muse, mutect2
- DNAH5 | c.11188A>G p.R3730G | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV54236096; called by muse, mutect2, varscan2
- FGD3 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV61598399; called by muse, mutect2, varscan2
- FRMPD2 | c.1820G>A p.S607N | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs540210045, COSV59719755; called by muse, mutect2, varscan2
- HTR3C | c.1058A>T p.H353L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.297); catalogued as rs1404935077, COSV59176374; called by muse, mutect2, varscan2
- IGHV1-12 | n.46G>T | Splice Region (SNP) | VAF 20/59 reads (34%) | catalogued as rs370218483; called by muse, mutect2, varscan2
- NEK10 | c.1595G>C p.C532S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58285715; called by muse, mutect2, varscan2
- OR5B2 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs777308368, COSV56908801; called by muse, mutect2, varscan2
- PTPRK | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as COSV63888027; called by muse, mutect2, varscan2
- SCN1A | c.2735T>C p.F912S (on ENST00000303395 / NM_001202435.3; = p.F901S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57675939; called by muse, mutect2, varscan2
- TEP1 | c.1510C>A p.L504I | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV52995135; called by muse, mutect2, varscan2
- VN1R1 | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs768749503, COSV58091349; called by muse, mutect2, varscan2
- VN1R1 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100320781, COSV58091370; called by muse, varscan2
- ZFAND3 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV54729058; called by muse, mutect2, varscan2
- SUGCT | c.1215G>A p.G405= (on ENST00000335693 / NM_001193313.2; = p.G431= on NM_024728.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/353 reads (5%) | catalogued as COSV59338395; called by muse, mutect2
- VN1R1 | c.180C>T p.I60= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV58090803, COSV58091361; called by muse, varscan2
